Somatic mutation profile of tumor specimen 0DCWBI from CCDI case PBBMLA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdoid tumor, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.4 years (146 days).
Specimen 0DCWBI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea0bea3c-0b4b-4ced-a260-7ed3e07cfd27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCWB6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fe03fdd-ef7d-4012-8cf5-80adcf6eaae7

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 1, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH1 | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 503/1321 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as rs543784627, COSV99877158; called by muse, mutect2, varscan2
- LBX2 | c.433G>T p.E145* (on ENST00000377566 / NM_001282430.2; = p.E141* on NM_001009812.2) | Nonsense Mutation (SNP) | VAF 32/825 reads (4%) | called by muse, mutect2
- KRT5 | c.1428C>T p.G476= | Silent (SNP) | VAF 316/796 reads (40%) | catalogued as rs565375836, COSV52859092; called by muse, mutect2, varscan2
